Somatic mutation profile of tumor specimen MP2PRT-PAVUME-TMP1-A (aliquot MP2PRT-PAVUME-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVUME, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,105 days).
Specimen MP2PRT-PAVUME-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80ffd2e9-7e5d-451e-8ca0-8121aa933e05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUME-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUME-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ce2b462-3a1e-4b8d-9bbf-25a0555113b0

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 56/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CD163 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 72/808 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs181334925, COSV63131936, COSV63133746; called by muse, mutect2
- DNAH5 | c.7633C>T p.R2545C | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1185501407; called by muse, mutect2, varscan2
- FBLN1 | c.1602C>A p.H534Q | Missense Mutation (SNP) | VAF 60/578 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1250877517; called by muse, mutect2, varscan2
- TRIM3 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 76/674 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1421453920; called by muse, mutect2, varscan2
- CHADL | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 134/1023 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.4785C>T p.A1595= | Silent (SNP) | VAF 49/428 reads (11%) | catalogued as rs932106643; called by muse, mutect2, varscan2
- COL6A2 | c.411G>A p.A137= | Silent (SNP) | VAF 102/796 reads (13%) | catalogued as rs528885146; ClinVar: uncertain significance; called by muse, varscan2
- KIF13B | c.2988G>A p.L996= | Silent (SNP) | VAF 54/474 reads (11%) | called by muse, mutect2, varscan2
- MAPK4 | c.1413C>A p.P471= | Silent (SNP) | VAF 116/1047 reads (11%) | called by muse, mutect2, varscan2
- SBK3 | c.579G>A p.P193= | Silent (SNP) | VAF 101/845 reads (12%) | catalogued as rs940769962; called by muse, mutect2, varscan2
